Somatic mutation profile of tumor specimen MBCProject_6747_T1_WES (aliquot MBCProject_6747_T1_WES_1) from CMI case MBCProject_6747, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 53.1 years (19,411 days).
Specimen MBCProject_6747_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80a3e2e5-f07e-4ebb-a1c3-17641cad13da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6747_BLOOD_BC (Blood Derived Normal), aliquot MBCProject_6747_BLOOD_BC_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8975012d-c782-49e4-8ceb-a5f742b8f4fa

The open-access MAF lists 54 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 2, Intron 2, RNA 2, 3'UTR 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 47/149 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP1 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100028147; called by muse, mutect2
- ANKRD17 | c.6275C>T p.P2092L | Missense Mutation (SNP) | VAF 127/475 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1443038945; called by muse, mutect2, varscan2
- CHGB | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as rs553869356, COSV66759863; called by muse, mutect2, varscan2
- FLCN | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53260392; called by muse, mutect2
- GATA3 | c.1071dup p.K358Efs*13 | Frame Shift Ins (INS) | VAF 88/332 reads (27%) | catalogued as COSV99062050; called by mutect2, pindel, varscan2
- MUC16 | c.10717C>T p.R3573C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as rs759791911, COSV67460075; called by muse, mutect2, varscan2
- PCDHGA4 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); catalogued as rs551700676; called by muse, mutect2, varscan2
- PHF24 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs536419897, COSV99646410; called by muse, mutect2, varscan2
- TMPRSS6 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100696120; called by muse, mutect2, varscan2
- USP38 | c.1594C>T p.L532F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1361198228; called by muse, mutect2, varscan2
- ZBED2 | c.379del p.H127Tfs*65 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | catalogued as COSV99343762; called by pindel, varscan2
- AFG3L2 | c.1859A>G p.Q620R | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP1A4 | c.2787dup p.V930Cfs*79 | Frame Shift Ins (INS) | VAF 17/125 reads (14%) | called by mutect2, pindel, varscan2
- CBFB | c.268del p.R90Efs*8 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | called by mutect2, pindel, varscan2
- CKMT2 | c.181A>G p.N61D | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAM186A | c.1621A>T p.M541L | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXA1 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- GPC2 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.111); called by muse, mutect2
- IDH3G | c.82-1G>T p.X28_splice | Splice Site (SNP) | VAF 15/65 reads (23%) | called by mutect2, varscan2
- LOXL3 | c.1218C>A p.C406* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2
- LSM14B | c.40A>T p.I14F | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MAP2K4 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MDGA2 | c.2329A>T p.I777F (on ENST00000399232 / NM_001113498.2; = p.I479F on NM_182830.4) | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- MYO9B | c.2897G>C p.W966S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NLN | c.121A>T p.T41S | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHN1 | c.1682C>A p.S561Y (on ENST00000379409; = p.S509Y on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PPFIBP2 | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- PRDM4 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC4A5 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPACA1 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- SPATA31D1 | c.3206C>A p.S1069Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SRCAP | c.108T>A p.S36R | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- TAS2R31 | c.63T>A p.N21K | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, varscan2
- TMEM151A | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TYR | c.1262A>T p.N421I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFP92 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP5 | c.2406T>G p.S802= | Silent (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.2052G>A p.R684= | Silent (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- DMRTC2 | c.1041C>T p.P347= | Silent (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- DNAH17 | c.5142G>A p.R1714= | Silent (SNP) | VAF 35/134 reads (26%) | called by muse, mutect2, varscan2
- NSFL1C | c.132C>T p.D44= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as rs191322139, COSV53792185; called by muse, mutect2, varscan2
- PDE6B | c.300C>T p.R100= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2
- PSIP1 | c.60T>C p.H20= | Silent (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
- SLCO2A1 | c.1371G>C p.P457= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as rs199835859; called by muse, mutect2, varscan2
- TNR | c.1881G>A p.V627= | Silent (SNP) | VAF 41/184 reads (22%) | called by muse, mutect2, varscan2
- VSIG1 | c.672C>A p.I224= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV54257528; called by muse, mutect2, varscan2
- ABHD11 | c.633+19C>T | Intron (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
- ASCC1 | c.*631_*633del | 3'UTR (DEL) | VAF 42/124 reads (34%) | called by mutect2, pindel, varscan2
- CARF | c.-82C>T | 5'UTR (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- FAM90A20P | n.1189C>T | RNA (SNP) | VAF 30/209 reads (14%) | catalogued as rs758782652; called by muse, mutect2, varscan2
- JPH2 | c.*2C>T | 3'UTR (SNP) | VAF 35/232 reads (15%) | catalogued as rs376077213; called by muse, mutect2, varscan2
- KIF19 | c.1587+16G>A | Intron (SNP) | VAF 10/86 reads (12%) | catalogued as rs1393335388; called by muse, mutect2
- RFPL4AP1 | n.763G>A | RNA (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
